Somatic mutation profile of tumor specimen TCGA-2Y-A9H1-01A (aliquot TCGA-2Y-A9H1-01A-11D-A382-10) from TCGA case TCGA-2Y-A9H1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.1 years (21,222 days).
Specimen TCGA-2Y-A9H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 627c01b3-3ad7-4418-8e26-bdfb967ee796.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H1-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H1-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a959c192-a8fa-46a8-b95d-c3396dcd2705

The open-access MAF lists 138 somatic variants for this specimen: 108 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 27, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 3, Intron 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 51/141 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs754435292, COSV99297847; called by muse, mutect2, varscan2
- AARD | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 206/541 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100991843; called by muse, mutect2, varscan2
- ABCA13 | c.10865T>C p.M3622T | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101446871; called by muse, mutect2, varscan2
- ADAM12 | c.612+2T>C p.X204_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100900157; called by muse, mutect2, varscan2
- ADAM28 | c.1624G>T p.G542W | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191658345, COSV99738151; called by muse, mutect2, varscan2
- ADAMTS19 | c.1265T>C p.L422S | Missense Mutation (SNP) | VAF 163/334 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as COSV50748578, COSV99176656; called by muse, mutect2, varscan2
- ADGRG4 | c.1677C>A p.F559L | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs767760760, COSV54953445, COSV99794818; called by muse, mutect2, varscan2
- ADGRL3 | c.2924G>A p.S975N (on ENST00000506720 / NM_001322402.2; = p.S907N on NM_015236.6) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763431457, COSV101546927; called by muse, mutect2, varscan2
- ALDH1B1 | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100890901, COSV66620133; called by muse, mutect2, varscan2
- APOBEC3A | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); catalogued as COSV99970318; called by muse, mutect2, varscan2
- ARIH2 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.236); catalogued as rs144088007; called by muse, mutect2, varscan2
- ASIC4 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100761613; called by muse, mutect2, varscan2
- ATP8A1 | c.2625G>T p.W875C | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100045407; called by muse, mutect2, varscan2
- ATXN1 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.471); catalogued as COSV99785624, COSV99787930; called by muse, mutect2, varscan2
- C8B | c.1771T>G p.S591A | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100980724; called by muse, mutect2, varscan2
- CARMIL2 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100576006; called by muse, mutect2, varscan2
- CCDC59 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.289); catalogued as rs759432434, COSV99810555; called by muse, mutect2, varscan2
- CCZ1 | c.1409T>G p.L470R | Missense Mutation (SNP) | VAF 196/629 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382739; called by muse, mutect2, varscan2
- CD1B | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.161); catalogued as COSV100939169; called by muse, mutect2, varscan2
- CDCP1 | c.1774A>T p.K592* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99943913; called by muse, mutect2, varscan2
- CHD2 | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101244890; called by muse, mutect2, varscan2
- CLEC6A | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101165624; called by muse, mutect2, varscan2
- COG1 | c.1433A>T p.E478V | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100245220; called by muse, mutect2, varscan2
- COL11A1 | c.2576G>T p.G859V | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100615542; called by muse, mutect2, varscan2
- CSMD1 | c.6277C>T p.P2093S (on ENST00000520002; = p.P2092S on NM_033225.6) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100145347; called by muse, mutect2, varscan2
- CWC27 | c.600-1G>A p.X200_splice | Splice Site (SNP) | VAF 153/318 reads (48%) | catalogued as COSV101126463; called by muse, mutect2, varscan2
- CYTIP | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99938675; called by muse, mutect2, varscan2
- DCUN1D1 | c.521-1G>T p.X174_splice | Splice Site (SNP) | VAF 149/515 reads (29%) | catalogued as COSV99489762; called by muse, mutect2, varscan2
- EIF5A | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1447521760, COSV100222804, COSV59749342; called by muse, mutect2, varscan2
- FAM160A2 | c.2074T>A p.S692T (on ENST00000449352 / NM_001098794.2; = p.S706T on NM_032127.4) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99791848; called by muse, mutect2, varscan2
- FLG2 | c.3329G>A p.G1110D | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV101165583, COSV101165691; called by muse, mutect2, varscan2
- FMNL2 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV99979143; called by muse, mutect2, varscan2
- GAS2L1 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53330644, COSV99329449; called by muse, mutect2, varscan2
- GAS2L3 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as COSV99902737; called by muse, mutect2, varscan2
- GFRA2 | c.472A>G p.S158G | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100151525; called by muse, mutect2, varscan2
- GNAZ | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50740859, COSV99320539; called by muse, mutect2, varscan2
- HADHB | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100501927; called by muse, mutect2, varscan2
- HERC2 | c.9919G>A p.E3307K | Missense Mutation (SNP) | VAF 131/445 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99871812; called by muse, varscan2
- HIPK2 | c.1154G>A p.W385* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100702099; called by muse, mutect2, varscan2
- IGLV3-27 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs570338405; called by muse, mutect2, varscan2
- KDM4A | c.3159T>G p.Y1053* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99495085; called by muse, mutect2, varscan2
- KLHDC1 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 283/777 reads (36%) | catalogued as COSV100833499; called by muse, mutect2, varscan2
- LAMA3 | c.4507G>A p.V1503M | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247572677, COSV100555856; called by muse, mutect2
- LCT | c.4964T>C p.L1655P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99928920; called by muse, mutect2, varscan2
- LMBR1L | c.819G>C p.Q273H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.5); catalogued as COSV99918622; called by muse, mutect2, varscan2
- LMO7 | c.1558G>A p.D520N (on ENST00000357063; = p.D250N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as COSV100412702; called by muse, mutect2
- LRRC7 | c.3313G>C p.A1105P (on ENST00000651989 / NM_001370785.2; = p.A1072P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99225352, COSV99230669; called by muse, mutect2, varscan2
- MAGEL2 | c.2609A>G p.E870G | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV100045809, COSV58568748; called by muse, mutect2, varscan2
- MED17 | c.740T>G p.I247S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99315810; called by muse, mutect2, varscan2
- MFSD11 | c.257A>T p.Y86F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100333599; called by muse, mutect2, varscan2
- MIGA1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100889753, COSV100889816; called by muse, mutect2, varscan2
- MRPL28 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV99170610; called by muse, mutect2, varscan2
- NCAN | c.3151C>G p.L1051V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs374113750, COSV99386802; called by muse, mutect2, varscan2
- NIPAL2 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100358314; called by muse, mutect2
- NPY2R | c.861C>A p.F287L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV100279535; called by muse, mutect2, varscan2
- NPY2R | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 33/124 reads (27%) | catalogued as COSV61529527; called by muse, mutect2, varscan2
- NUP214 | c.4615A>T p.K1539* | Nonsense Mutation (SNP) | VAF 41/109 reads (38%) | catalogued as COSV100845190; called by muse, mutect2, varscan2
- OCIAD1 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99971083; called by muse, mutect2, varscan2
- OR4K13 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV100237667; called by muse, mutect2, varscan2
- OR51A7 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100834611; called by muse, mutect2, varscan2
- PADI2 | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1268779053, COSV100971838; called by muse, mutect2, varscan2
- PCDH11X | c.2486T>C p.F829S | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100009688; called by muse, mutect2
- PCDHA13 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV99165313; called by muse, mutect2, varscan2
- PCDHA8 | c.2084A>G p.D695G | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs1449552698, COSV100969232; called by muse, mutect2, varscan2
- PGR | c.2111A>G p.D704G | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99677670; called by muse, mutect2, varscan2
- PI16 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028632; called by muse, mutect2, varscan2
- PITX3 | c.19A>C p.S7R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.053); catalogued as COSV100892766, COSV64174884; called by muse, mutect2, varscan2
- PKHD1L1 | c.2924C>A p.T975K | Missense Mutation (SNP) | VAF 130/385 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV101005703; called by muse, mutect2, varscan2
- PLD3 | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100735128; called by muse, mutect2, varscan2
- PNPLA7 | c.2951A>G p.K984R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.278); catalogued as COSV99480325; called by muse, mutect2, varscan2
- POP1 | c.2906A>T p.Q969L | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100855688; called by muse, mutect2, varscan2
- PPP2CA | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99196029; called by muse, mutect2, varscan2
- PREX2 | c.3484C>A p.L1162I | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99905803; called by muse, mutect2, varscan2
- PRKAB2 | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99567853; called by muse, mutect2, varscan2
- PRSS12 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99627927, COSV99628148; called by muse, mutect2, varscan2
- PTGFR | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882255; called by muse, mutect2, varscan2
- RECQL5 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100511714; called by muse, mutect2, varscan2
- RNF148 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100411503; called by muse, mutect2, varscan2
- RTP5 | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.429); catalogued as COSV100574687; called by muse, mutect2, varscan2
- SAMD1 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99513749; called by muse, mutect2, varscan2
- SCO2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV99329407; called by muse, mutect2, varscan2
- SIGLEC8 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as COSV100367188, COSV58473821; called by muse, mutect2, varscan2
- SIRPG | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs370649250; called by muse, mutect2, varscan2
- SLC36A3 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100077442; called by muse, mutect2, varscan2
- SLC4A2 | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59658974; called by muse, mutect2, varscan2
- SPTBN1 | c.3329A>T p.E1110V | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100442060; called by muse, mutect2, varscan2
- STAP1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99609245; called by muse, mutect2, varscan2
- STAT1 | c.1090T>C p.F364L | Missense Mutation (SNP) | VAF 172/482 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs759722579, COSV100699962; ClinVar: benign; called by muse, mutect2, varscan2
- TGFB1I1 | c.1355G>A p.C452Y (on ENST00000394863 / NM_001042454.3; = p.C435Y on NM_015927.4) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221829945, COSV100690958; called by muse, mutect2, varscan2
- TIAM2 | c.607A>C p.T203P | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV100018301; called by muse, mutect2, varscan2
- TNR | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.585); catalogued as COSV99688369; called by muse, mutect2, varscan2
- TRAPPC10 | c.91A>C p.T31P | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99378329; called by muse, mutect2, varscan2
- TRERF1 | c.2053A>G p.S685G | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100550212; called by muse, mutect2, varscan2
- TSHZ2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs772450298, COSV100295625; called by muse, mutect2, varscan2
- VCAN | c.8195C>A p.A2732E | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425079; called by muse, mutect2, varscan2
- VWA8 | c.4949A>T p.Q1650L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs544413664, COSV101022437; called by muse, mutect2, varscan2
- WNK2 | c.2099C>A p.P700Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as COSV99941421; called by muse, mutect2, varscan2
- ZBTB22 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.932); catalogued as COSV99801700; called by muse, mutect2, varscan2
- ZDHHC1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100799372; called by muse, mutect2, varscan2
- ZNF347 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100498186; called by muse, mutect2, varscan2
- ZNF468 | c.710A>C p.H237P | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99700416; called by muse, mutect2, varscan2
- ZNF512B | c.2371A>C p.K791Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99411648; called by muse, mutect2, varscan2
- FGB | c.248dup p.K84Efs*8 | Frame Shift Ins (INS) | VAF 52/176 reads (30%) | called by mutect2, varscan2
- GPR78 | c.1022del p.P341Rfs*35 | Frame Shift Del (DEL) | VAF 58/234 reads (25%) | called by mutect2, pindel, varscan2
- INA | c.1418_1447del p.I473_K482del | In Frame Del (DEL) | VAF 46/200 reads (23%) | called by pindel, varscan2
- PCDHB10 | c.1475del p.P492Rfs*50 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- PTPN21 | c.246del p.K82Nfs*3 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- C16orf71 | c.990G>T p.R330= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs1447294658, COSV99556218; called by muse, mutect2, varscan2
- CAMSAP3 | c.198G>T p.A66= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as rs775060609, COSV50338851, COSV99350105; called by muse, mutect2, varscan2
- CLDN14 | c.453G>A p.L151= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100578498; called by muse, mutect2, varscan2
- DUSP26 | c.507G>A p.L169= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99823354; called by muse, mutect2, varscan2
- ELOVL1 | c.183C>T p.F61= | Silent (SNP) | VAF 61/183 reads (33%) | catalogued as COSV100196373; called by muse, mutect2, varscan2
- ERP44 | c.489C>A p.I163= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99316273; called by muse, mutect2, varscan2
- FLNB | c.675G>A p.V225= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs1252938015, COSV99912267; called by muse, mutect2, varscan2
- GABPB2 | c.561G>A p.T187= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as rs770812873, COSV100927194; called by muse, mutect2, varscan2
- GABRE | c.1080G>A p.V360= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100944238; called by muse, mutect2, varscan2
- GNL1 | c.951G>A p.G317= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100925399; called by muse, mutect2, varscan2
- IL9R | c.1053C>T p.C351= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs139866056, COSV99729504; called by muse, mutect2, varscan2
- IRF2BPL | c.957G>T p.S319= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV99467878; called by muse, mutect2, varscan2
- LTBP1 | c.1056C>A p.I352= (on ENST00000404816 / NM_206943.4; = p.I26= on NM_000627.4) | Silent (SNP) | VAF 67/235 reads (29%) | catalogued as COSV100616660; called by muse, mutect2, varscan2
- MASP2 | c.831C>G p.T277= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV101280108; called by muse, mutect2, varscan2
- MEGF6 | c.4524C>T p.P1508= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV53897718; called by muse, mutect2, varscan2
- MYH3 | c.4818G>A p.V1606= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs747613220, COSV99877926; called by muse, mutect2, varscan2
- NSD1 | c.6690A>G p.P2230= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100728601; called by muse, mutect2, varscan2
- ODF1 | c.534G>A p.P178= | Silent (SNP) | VAF 31/288 reads (11%) | catalogued as rs773452541, COSV53431550; called by muse, mutect2, varscan2
- OR10G4 | c.264C>A p.G88= | Silent (SNP) | VAF 92/298 reads (31%) | catalogued as COSV57978201; called by muse, varscan2
- PIGO | c.1848C>T p.H616= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs1348048933, COSV99956509; called by muse, mutect2, varscan2
- PLPP2 | c.240C>T p.D80= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99514531; called by muse, mutect2, varscan2
- PRAMEF17 | c.363C>T p.A121= | Silent (SNP) | VAF 95/249 reads (38%) | catalogued as COSV101068683; called by muse, mutect2, varscan2
- PREX2 | c.1221T>C p.P407= | Silent (SNP) | VAF 123/363 reads (34%) | catalogued as COSV99905801; called by muse, mutect2, varscan2
- SOX30 | c.354C>T p.G118= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs577314769, COSV99398260; called by muse, mutect2, varscan2
- UNC13D | c.1815G>T p.L605= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV99256248; called by muse, mutect2, varscan2
- WDR18 | c.330C>G p.T110= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV52122876, COSV99242728; called by muse, mutect2, varscan2
- WWC3 | c.2175G>A p.V725= | Silent (SNP) | VAF 99/140 reads (71%) | catalogued as COSV66502709; called by muse, mutect2, varscan2
- MACF1 | c.15832-9836C>T | Intron (SNP) | VAF 60/157 reads (38%) | catalogued as COSV99242467; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792407 G>A | 3'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- TGIF1 | chr18:3447756 A>G | 5'Flank (SNP) | VAF 49/126 reads (39%) | catalogued as COSV100394755; called by muse, mutect2, varscan2
